Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6934, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6934-01A (Primary Tumor).

[page 1 of 3]
DIAGNOSIS

- (A) BIOPSY, RIGHT ORAL TONGUE:
INVASIVE SQUAMOUS CARCINOMA.
- (B) BILATERAL NECK DISSECTION, TOTAL LARYNGECTOMY, TOTAL GLOSSECTOMY AND SEGMENTAL MANDIBULECTOMY:
INVASIVE SQUAMOUS CARCINOMA OF TONGUE, TUMOR PRESENT APPROXIMATELY 1.0 MM FROM DEEP RESECTION MARGIN, LATERAL MARGIN OF RESECTION FREE OF TUMOR.
EXTENSIVE PERINEURAL INVASION PRESENT.
Eighteen left level I axillary neck lymph nodes, negative for tumor.
METASTATIC SQUAMOUS CARCINOMA IN 2 OF 4 LEFT LEVEL II NECK LYMPH NODES.
METASTATIC CARCINOMA GROSSLY MEASURES APPROXIMATELY 2.0 CM IN DIAMETER COMPLETELY REPLACES THE INVOLVED LYMPH NODES.
EXTRANODAL EXTENSION TO ADIPOSE TISSUE PRESENT.
METASTATIC SQUAMOUS CARCINOMA IN 1 OF 7 LEVEL III LYMPH NODES.
Five left level IV lymph nodes, negative for tumor.
Right submandibular gland, negative for tumor.
Three right level III and IV lymph nodes, negative for tumor.
- (C) PALATAL MARGIN:
Squamous mucosa with foci of mild dysplasia, no tumor present.
- (D) ANTERIOR MUCOSAL MARGIN:
Squamous mucosa, no tumor present.
- (E) TEETH:
Multiple teeth (gross description only) squamous mucosa shows mild to moderate chronic inflammation.

Entire report and diagnosis completed by: [REDACTED]

Report released by: [REDACTED]

GROSS DESCRIPTION

- (A) BIOPSY, RIGHT ORAL TONGUE - Two fragments of tan and pink-red soft tissue, measuring 1.0 x 0.5 x 0.3 cm and 0.6 x 0.5 x 0.4 cm. Entirely submitted for frozen section as A. [REDACTED]
- *FS/DX: DIFFERENTIATED INVASIVE SQUAMOUS CARCINOMA. [REDACTED]
- (B) BILATERAL NECK DISSECTION, TOTAL LARYNGECTOMY, TOTAL GLOSSECTOMY AND SEGMENTAL MANDIBULECTOMY - A total tongue resection (12.8 x 4.5 x 4.2 cm), attached segmental resection of right mandible (9.6 x 2.8 x 0.8 cm), and intact larynx (5.0 x 3.3 x 2.5 cm) with epiglottis and hyoid bone. Bilateral neck dissections are attached, measuring 12.5 x 4.8 x 1.5 cm on the right and 7.0 x 4.5 x 1.2 cm on the left. The left level I region contains multiple pink to dark red soft lymph nodes, ranging from 0.2 to 1.3 cm in greatest dimension. No gross tumor is identified. The left level II region contains multiple lymph nodes, ranging from 0.2 up to 3.0 cm in greatest dimension. Two

[page 2 of 3]
lymph nodes grossly involved by tumor are identified. The left level III region contains multiple lymph nodes ranging from 0.3 to 0.7 cm in greatest dimension. No gross tumor is identified. The left level IV region contains multiple lymph nodes, ranging from 0.2 to 0.5 cm in greatest dimension. No gross tumor is identified. The right level I region contains an unremarkable salivary gland measuring 3.8 x 2.3 x 1.3 cm. No lymph nodes are identified. The right level II region contains an unremarkable salivary gland measuring 3.0 cm. Two additional lymph nodes are present, measuring 0.3 to 0.5 cm in greatest dimension, respectively. The right level III and IV regions contain multiple lymph nodes, ranging from 0.1 to 0.4 cm in greatest dimension. No gross tumor is identified.

A tan-pink, rubbery circumscribed mass (8.5 x 4.0 x 3.0 cm), occupies the entire right side of the tongue. An area of ulceration (4.7 x 2.4 cm) is present overlying the mass on the right lateral aspect of the tongue. The remaining mucosa on the tongue is intact. The mass is 0.5 cm from the closest right lateral mucosal margin, 1.1 cm from the closest anterior mucosal margin and 1.4 cm from the closest left lateral mucosal margin. The tumor approaches within 1.0 mm of the deep soft tissue in the region overlying the tumor in the tongue base and anterior tongue.

Mucosa with ulceration and tumor is adherent to the medial portion of the mandibular segment. This bone segment is submitted to the Bone Lab for further sections and processing.

The larynx is grossly unremarkable with the base of the epiglottis approximately 1.0 cm from the closest tumor and bone base.

Portions of tumor and normal tissue are submitted for research protocol and flow cytometry.

INK CODE: Yellow-mucosal surgical margins; black-deep soft tissue margins.

SECTION CODE: B1-B3, right tongue base tumor and deep margin; B4, right anterior tongue tumor and deep margin; B5, left lateral anterior tongue mucosal margin; B6, left lateral posterior tongue mucosal margin; B7-B10, tongue tumor and mucosa; B11-B13, tumor and ulcerated surface; B14, left pyriform sinus margin; B15, inferior laryngeal mucosal margin; B16, right pyriform sinus margin; B17, left true and false vocal cord; B18, right true and false vocal cord; B19, epiglottis; B20-B25, left level I lymph nodes (20-21, three lymph nodes per cassette; B22, four lymph nodes; B23, two lymph nodes; B24-B25, three lymph nodes per cassette); B26-B28, left level II lymph nodes (B26, representative cross section of grossly positive lymph node; B27, representative section of second grossly positive lymph node; B28, two possible lymph nodes); B29-B30, left level III lymph nodes (3 possible lymph nodes per cassette); B31-B32, left level IV lymph nodes (B31, three possible lymph nodes; B32, two possible lymph nodes); B33, right level I salivary gland; B34-B36, right level II lymph nodes (B34, salivary gland; B35, one bisected lymph node; B36, one lymph node); B37-B38, right level III-IV lymph nodes (B37, three possible lymph node; B38, two possible lymph nodes).

(C) PALATAL MARGIN - An oval, tan-pink soft tissue specimen (3.3 x 0.4 x 0.3 cm). The true margin is indicated to be away from the ink side and a single suture is present at the inferior aspect. No focal lesions are identified.

SECTION CODE: C1, superior half, en face for frozen section; C2, inferior half, en face for frozen section.

*ES/DX: SQUAMOUS MUCOSA WITH FOCI OF MILD DYSPLASIA, NO TUMOR PRESENT.

(D) ANTERIOR MUCOSAL MARGIN - A tan-pink mucosal fragment (3.0 x 0.2 x 0.2

[page 3 of 3]
[REDACTED]

cm). An ink dot is present on the mucosal surface which is indicated as a true margin. A white-tan, fibrous nodule (0.4 x 0.3 x 0.2 cm) is present.

SECTION CODE: D1-D2, entire true margin, submitted en face for frozen section. [REDACTED]

(E) TEETH - Multiple anterior teeth and tooth fragments, some of which have focal metallic material on the exterior surfaces; two teeth appear to have porcelain crowns, and there are focal caries. Minimal adherent soft tissue is present. Soft tissue submitted as E. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d3626d3e-56d2-41a0-bf25-2c26765485e5 (TCGA-CV-6934.E7D042AF-8D11-4E79-AEFA-9715A4958799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).